Somatic mutation profile of tumor specimen MP2PRT-PAVAGF-TMP1-A (aliquot MP2PRT-PAVAGF-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVAGF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (938 days).
Specimen MP2PRT-PAVAGF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae2ccb30-c333-4e4e-a6d6-41756b6540b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAGF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAGF-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/664e49be-6aee-4acf-bab2-1dbed9d36b73

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, In Frame Ins 1, Silent 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSPA12A | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 101/469 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as rs1554877456; called by muse, mutect2, varscan2
- KHSRP | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101231182; called by muse, mutect2, varscan2
- MYO1A | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 84/344 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs138932052; called by muse, mutect2, varscan2
- PAX5 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63907754, COSV63909300; called by muse, varscan2
- PRXL2A | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11540475, COSV100939790; called by muse, mutect2, varscan2
- SLC4A9 | c.1246G>A p.V416I (on ENST00000507527 / NM_001258428.2; = p.V392I on NM_031467.3) | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.03); catalogued as rs370749982; called by muse, varscan2
- TWNK | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs781016340; called by muse, mutect2, varscan2
- ZHX1 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 36/184 reads (20%) | catalogued as rs777615439, COSV99933647; called by muse, mutect2, varscan2
- NLN | c.1316T>C p.L439P | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PBX1 | c.776_777insGGGCCC p.P259_Y260insGP | In Frame Ins (INS) | VAF 45/282 reads (16%) | called by mutect2, pindel, varscan2
- BSN | c.10398C>T p.Y3466= | Silent (SNP) | VAF 137/520 reads (26%) | catalogued as rs377295244, COSV56520112; called by muse, mutect2, varscan2
- APLP2 | c.105+560C>T | Intron (SNP) | VAF 95/492 reads (19%) | called by muse, mutect2, varscan2
